Somatic mutation profile of tumor specimen TCGA-BR-A4CS-01A (aliquot TCGA-BR-A4CS-01A-11D-A24D-08) from TCGA case TCGA-BR-A4CS, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Fundus of stomach; AJCC pathologic stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 77.2 years (28,211 days).
Specimen TCGA-BR-A4CS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ee898cc6-1718-4fec-9ce4-06750e6afd12.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-A4CS-10A (Blood Derived Normal), aliquot TCGA-BR-A4CS-10A-01D-A24F-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/918c4840-d582-4426-be3a-b4720d6f631b

The open-access MAF lists 157 somatic variants for this specimen: 122 protein-altering or splice-affecting, 34 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 99, Silent 34, Nonsense Mutation 9, Frame Shift Del 6, Frame Shift Ins 4, Splice Site 2, In Frame Del 1, Splice Region 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.725G>C p.C242S | Missense Mutation (SNP) | VAF 39/115 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912655, CM910618, COSV52661189, COSV52677418, COSV52689710; called by muse, mutect2, varscan2
- ABCD2 | c.1639C>T p.P547S | Missense Mutation (SNP) | VAF 36/243 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58049882, COSV58056093; called by muse, mutect2, varscan2
- AKAP13 | c.6038del p.L2013Pfs*4 (on ENST00000394518 / NM_007200.5; = p.L2017Pfs*4 on NM_006738.6) | Frame Shift Del (DEL) | VAF 13/118 reads (11%) | catalogued as COSV63453042; called by mutect2, pindel, varscan2
- ATAD5 | c.3410G>A p.G1137E | Missense Mutation (SNP) | VAF 26/198 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58972402; called by muse, mutect2, varscan2
- ATP10B | c.2002G>T p.V668L | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV59144766, COSV59157722; called by muse, mutect2, varscan2
- B3GALNT2 | c.1421_1423del p.P474del | In Frame Del (DEL) | VAF 16/150 reads (11%) | catalogued as rs752758430; called by pindel, varscan2
- BEND2 | c.1888G>T p.E630* | Nonsense Mutation (SNP) | VAF 39/110 reads (35%) | catalogued as COSV66215202; called by muse, mutect2, varscan2
- BRD1 | c.1265C>A p.S422Y | Missense Mutation (SNP) | VAF 51/325 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.641); catalogued as COSV53455132; called by muse, mutect2, varscan2
- BRWD3 | c.1678G>A p.D560N | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64744471; called by muse, mutect2
- CAVIN3 | c.25G>A p.G9R | Missense Mutation (SNP) | VAF 137/171 reads (80%) | SIFT deleterious (0.04); PolyPhen benign (0.127); catalogued as COSV58268618; called by muse, mutect2, varscan2
- CCDC40 | c.1542G>T p.R514S | Missense Mutation (SNP) | VAF 25/137 reads (18%) | SIFT tolerated (0.59); PolyPhen benign (0.007); catalogued as COSV53897320; called by muse, mutect2, varscan2
- CCN5 | c.7G>A p.G3S | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.115); catalogued as COSV51936084; called by muse, mutect2
- CD180 | c.280G>T p.E94* | Nonsense Mutation (SNP) | VAF 30/128 reads (23%) | catalogued as COSV56517032; called by muse, mutect2, varscan2
- CDC42BPG | c.3482C>A p.A1161E | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.028); catalogued as rs774031724, COSV61345842; called by muse, mutect2, varscan2
- CDH10 | c.2032C>A p.P678T | Missense Mutation (SNP) | VAF 33/161 reads (20%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.989); catalogued as COSV52571783, COSV52598751; called by muse, mutect2, varscan2
- CDH12 | c.2280A>C p.E760D | Missense Mutation (SNP) | VAF 44/162 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV66390541; called by muse, mutect2, varscan2
- CDH9 | c.1566A>C p.K522N | Missense Mutation (SNP) | VAF 58/249 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.477); catalogued as rs1216936998, COSV50254544; called by muse, mutect2, varscan2
- CFH | c.1928A>G p.E643G | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV66406244; called by muse, mutect2, varscan2
- CLEC12A | c.574G>C p.G192R | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.85); catalogued as COSV58560616; called by muse, mutect2
- CMYA5 | c.3403G>A p.V1135M | Missense Mutation (SNP) | VAF 26/123 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.006); catalogued as COSV71404287; called by muse, mutect2, varscan2
- COL27A1 | c.2375C>A p.P792H | Missense Mutation (SNP) | VAF 18/158 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61922198; called by muse, mutect2, varscan2
- COL8A1 | c.1171G>A p.E391K | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.66); PolyPhen benign (0.091); catalogued as rs267599510, COSV53730162; called by muse, mutect2, varscan2
- CPNE4 | c.583C>T p.R195* | Nonsense Mutation (SNP) | VAF 10/79 reads (13%) | catalogued as COSV101456747, COSV70190669; called by muse, mutect2, varscan2
- CYP19A1 | c.1332G>A p.M444I | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.951); catalogued as COSV53057556; called by muse, mutect2, varscan2
- CYP4B1 | c.1036C>T p.R346C | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.082); catalogued as rs56180718, COSV54721587; called by muse, mutect2, varscan2
- DAB2IP | c.39C>T p.Y13= | Splice Region (SNP) | VAF 45/224 reads (20%) | catalogued as rs201252302, COSV52255139; called by muse, mutect2, varscan2
- DDR1 | c.1598C>T p.A533V | Missense Mutation (SNP) | VAF 66/305 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.018); catalogued as COSV61319622; called by muse, mutect2, varscan2
- DNAH10 | c.6500G>A p.R2167H (on ENST00000409039; = p.R2106H on NM_207437.3) | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as rs766596956, COSV68988967; called by muse, mutect2, varscan2
- DNAH11 | c.13303G>T p.G4435C | Missense Mutation (SNP) | VAF 65/116 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1044815255, COSV60942560; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAJC13 | c.218G>A p.R73H | Missense Mutation (SNP) | VAF 19/127 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs547360849, COSV53446557; called by muse, mutect2, varscan2
- DPP10 | c.214G>C p.E72Q | Missense Mutation (SNP) | VAF 33/119 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.817); catalogued as COSV100067299, COSV59667988; called by muse, mutect2, varscan2
- DRP2 | c.2519G>A p.R840H | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.277); catalogued as rs180918321, COSV67870669, COSV67871686; called by muse, mutect2, varscan2
- DSG3 | c.655C>T p.R219C | Missense Mutation (SNP) | VAF 37/197 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.189); catalogued as rs779202575, COSV57124569; called by muse, mutect2, varscan2
- EFNB3 | c.389G>A p.R130H | Missense Mutation (SNP) | VAF 28/142 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.846); catalogued as rs955148669, COSV56832895; called by muse, mutect2, varscan2
- ENKUR | c.736A>T p.K246* | Nonsense Mutation (SNP) | VAF 12/80 reads (15%) | catalogued as COSV58632522; called by muse, mutect2, varscan2
- F13A1 | c.1862C>A p.A621D | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV53554220; called by muse, mutect2, varscan2
- FAM71C | c.647A>C p.E216A | Missense Mutation (SNP) | VAF 38/249 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.065); catalogued as COSV60942714; called by muse, mutect2, varscan2
- FBN3 | c.6080C>A p.S2027* | Nonsense Mutation (SNP) | VAF 16/74 reads (22%) | catalogued as COSV54454654; called by muse, mutect2, varscan2
- FLNB | c.5842C>T p.R1948* | Nonsense Mutation (SNP) | VAF 6/36 reads (17%) | catalogued as rs775301566, COSV55872193; called by muse, mutect2, varscan2
- FREM2 | c.1201G>A p.D401N | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.908); catalogued as COSV54830221; called by muse, mutect2, varscan2
- GFRA3 | c.1134G>C p.R378S | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.382); catalogued as COSV51228002; called by muse, mutect2, varscan2
- GJA8 | c.343G>A p.G115S | Missense Mutation (SNP) | VAF 24/122 reads (20%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as rs782663112, COSV53787956; called by muse, mutect2, varscan2
- GPR17 | c.606G>T p.Q202H | Missense Mutation (SNP) | VAF 74/219 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as COSV55754172; called by muse, mutect2, varscan2
- GPRIN3 | c.484T>C p.S162P | Missense Mutation (SNP) | VAF 33/150 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV60884251; called by muse, mutect2, varscan2
- GRM2 | c.1393C>T p.R465C | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.772); catalogued as rs200690482, COSV56583445; called by muse, mutect2, varscan2
- GRM8 | c.1118C>G p.S373* | Nonsense Mutation (SNP) | VAF 22/102 reads (22%) | catalogued as COSV58806551; called by muse, mutect2, varscan2
- HHIP | c.265C>T p.R89C | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.465); catalogued as rs957635442, COSV56836981; called by muse, mutect2, varscan2
- HLA-C | c.1097C>G p.A366G | Missense Mutation (SNP) | VAF 21/136 reads (15%) | SIFT tolerated, low confidence (0.58); PolyPhen probably damaging (0.989); catalogued as COSV66111211; called by muse, mutect2, varscan2
- HOXA13 | c.799G>A p.E267K | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as COSV56082991; called by muse, mutect2, varscan2
- HUWE1 | c.7033G>A p.E2345K | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as COSV53336433; called by muse, mutect2, varscan2
- IARS2 | c.1724C>G p.P575R | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV56957976; called by muse, mutect2, varscan2
- ITGB5 | c.1782C>G p.C594W | Missense Mutation (SNP) | VAF 21/129 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56146886; called by muse, mutect2, varscan2
- KCNS1 | c.1036C>G p.L346V | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60259413; called by muse, mutect2, varscan2
- KIRREL1 | c.1514C>T p.A505V | Missense Mutation (SNP) | VAF 23/221 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.338); catalogued as rs368818824; called by muse, mutect2, varscan2
- KMT2A | c.9205C>T p.P3069S | Missense Mutation (SNP) | VAF 44/221 reads (20%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.015); catalogued as COSV63282754; called by muse, mutect2, varscan2
- KRTAP19-6 | c.79T>G p.C27G | Missense Mutation (SNP) | VAF 45/239 reads (19%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.066); catalogued as COSV61843759; called by muse, mutect2, varscan2
- KRTAP4-1 | c.32C>A p.S11Y | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV66648013; called by muse, mutect2, varscan2
- LRRC4 | c.1103G>A p.R368Q | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT tolerated (0.55); PolyPhen benign (0.372); catalogued as COSV50813371, COSV99974732; called by muse, mutect2, varscan2
- LRRC7 | c.3545G>A p.G1182D (on ENST00000651989 / NM_001370785.2; = p.G1149D on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/180 reads (13%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.529); catalogued as COSV50416699; called by muse, mutect2, varscan2
- LRRIQ3 | c.1201G>C p.E401Q | Missense Mutation (SNP) | VAF 22/131 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.07); catalogued as COSV63041605; called by muse, mutect2, varscan2
- LRRK2 | c.3320A>T p.E1107V | Missense Mutation (SNP) | VAF 24/182 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.328); catalogued as COSV54145743; called by muse, mutect2, varscan2
- LZTS3 | c.273G>C p.K91N | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.92); catalogued as COSV100232204, COSV100232238; called by muse, mutect2, varscan2
- MED13L | c.1048G>A p.V350I | Missense Mutation (SNP) | VAF 24/208 reads (12%) | SIFT tolerated (0.4); PolyPhen benign (0.022); catalogued as COSV56116558; called by muse, mutect2, varscan2
- MKI67 | c.108C>G p.D36E | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as COSV64072860; called by muse, mutect2, varscan2
- MSC | c.451C>G p.L151V | Missense Mutation (SNP) | VAF 21/239 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV57696203; called by muse, mutect2
- MYO1H | c.2356G>A p.V786M | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.039); catalogued as rs765395658, COSV60443353; called by muse, mutect2, varscan2
- NBEA | c.6247C>T p.R2083C | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs200761216, COSV59763814; called by muse, mutect2
- NCAM2 | c.217G>T p.G73C | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.792); catalogued as COSV53059400; called by muse, mutect2, varscan2
- NLRC5 | c.3375_3376insT p.R1126Sfs*20 | Frame Shift Ins (INS) | VAF 6/32 reads (19%) | catalogued as COSV99346967; called by mutect2, pindel, varscan2
- NPBWR1 | c.685C>T p.R229W | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); catalogued as COSV58695523; called by muse, mutect2, varscan2
- OR14K1 | c.274T>G p.F92V | Missense Mutation (SNP) | VAF 20/136 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.147); catalogued as COSV99315098; called by muse, mutect2, varscan2
- OR5I1 | c.539dup p.C181Lfs*2 | Frame Shift Ins (INS) | VAF 14/87 reads (16%) | catalogued as rs757816304; called by mutect2, pindel, varscan2
- PAPPA2 | c.2756A>C p.D919A | Missense Mutation (SNP) | VAF 8/172 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV62791861; called by muse, mutect2
- PARP6 | c.797G>C p.G266A | Missense Mutation (SNP) | VAF 73/614 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV53002224; called by muse, mutect2, varscan2
- PBX1 | c.266-1G>C p.X89_splice | Splice Site (SNP) | VAF 8/52 reads (15%) | catalogued as COSV61532274; called by muse, mutect2, varscan2
- PCDHGB1 | c.763G>T p.G255* | Nonsense Mutation (SNP) | VAF 32/154 reads (21%) | catalogued as COSV53907779; called by muse, mutect2, varscan2
- PCSK6 | c.953C>T p.P318L | Missense Mutation (SNP) | VAF 51/275 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59338321; called by muse, mutect2, varscan2
- PDE3B | c.3028C>A p.P1010T | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56380248; called by muse, mutect2, varscan2
- PFKFB3 | c.169C>T p.R57C | Missense Mutation (SNP) | VAF 48/257 reads (19%) | PolyPhen possibly damaging (0.883); catalogued as COSV57987171; called by muse, mutect2, varscan2
- PLEKHG3 | c.2174C>T p.P725L (on ENST00000394691; = p.P781L on NM_001308147.2) | Missense Mutation (SNP) | VAF 27/134 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.075); catalogued as rs773978261, COSV55977995; called by muse, mutect2, varscan2
- PML | c.1238C>T p.P413L | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV51442919; called by muse, mutect2, varscan2
- PTPRU | c.3083G>A p.R1028H | Missense Mutation (SNP) | VAF 59/336 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs759323710, COSV60522856, COSV60524080; called by muse, mutect2, varscan2
- RAB22A | c.250G>A p.V84I | Missense Mutation (SNP) | VAF 14/256 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); catalogued as rs889683878, COSV54830300; called by muse, mutect2
- RBCK1 | c.1060C>A p.L354I (on ENST00000356286 / NM_031229.4; = p.L312I on NM_006462.6) | Missense Mutation (SNP) | VAF 17/132 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV62291732; called by muse, mutect2, varscan2
- RECQL | c.1726G>A p.A576T | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.939); catalogued as COSV53708278; called by muse, mutect2, varscan2
- SALL2 | c.1798G>T p.D600Y | Missense Mutation (SNP) | VAF 24/120 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58102252; called by muse, mutect2, varscan2
- SBF1 | c.1573C>T p.Q525* | Nonsense Mutation (SNP) | VAF 25/117 reads (21%) | catalogued as rs1556430212, COSV62366080; called by muse, mutect2, varscan2
- SERINC4 | c.887G>A p.C296Y | Missense Mutation (SNP) | VAF 47/313 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV51048692; called by muse, mutect2, varscan2
- SERPINA9 | c.964C>A p.L322I | Missense Mutation (SNP) | VAF 27/131 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV54073037, COSV54079359; called by muse, mutect2
- SERPINB7 | c.737T>C p.L246P | Missense Mutation (SNP) | VAF 41/169 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV60532788; called by muse, mutect2, varscan2
- SLC6A2 | c.1078G>A p.A360T | Missense Mutation (SNP) | VAF 30/265 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.21); catalogued as rs1345478335, COSV54913121; called by muse, mutect2, varscan2
- SLC9A9 | c.1360G>A p.E454K | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.089); catalogued as COSV57219757; called by muse, mutect2, varscan2
- SLCO1B1 | c.1193A>C p.K398T | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57007790; called by muse, mutect2, varscan2
- SPAG17 | c.2146G>C p.D716H | Missense Mutation (SNP) | VAF 10/223 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.471); catalogued as COSV100309858, COSV60453890; called by muse, mutect2
- STAG1 | c.2197-1G>C p.X733_splice | Splice Site (SNP) | VAF 6/70 reads (9%) | catalogued as COSV52603007, COSV99366610; called by muse, mutect2
- SULT1A1 | c.302C>G p.A101G | Missense Mutation (SNP) | VAF 39/234 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as COSV59086901; called by muse, mutect2, varscan2
- SVEP1 | c.2948del p.K983Rfs*12 | Frame Shift Del (DEL) | VAF 18/59 reads (31%) | catalogued as rs894024304; called by mutect2, pindel, varscan2
- SYNDIG1 | c.535C>T p.R179W | Missense Mutation (SNP) | VAF 34/384 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs770624311, COSV65232499; called by muse, mutect2
- SYNJ1 | c.1303T>G p.F435V | Missense Mutation (SNP) | VAF 39/107 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59144978; called by muse, mutect2, varscan2
- TCP11 | c.1316T>G p.V439G (on ENST00000512012; = p.V377G on NM_018679.5) | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.588); catalogued as COSV55132305; called by muse, mutect2, varscan2
- TENM3 | c.1415C>T p.A472V | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT tolerated (0.39); PolyPhen benign (0.021); catalogued as rs781339057, COSV69300252, COSV69308191; called by muse, mutect2, varscan2
- TFE3 | c.1703G>A p.S568N | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.021); catalogued as COSV59946109; called by muse, mutect2, varscan2
- TMF1 | c.52T>C p.S18P | Missense Mutation (SNP) | VAF 27/131 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.634); catalogued as COSV62739827; called by muse, mutect2, varscan2
- TNC | c.1570G>A p.G524S | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372037200; called by muse, mutect2, varscan2
- TOGARAM1 | c.3642G>T p.E1214D | Missense Mutation (SNP) | VAF 61/267 reads (23%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.546); catalogued as COSV63890771; called by muse, mutect2, varscan2
- TRIML1 | c.1080C>G p.D360E | Missense Mutation (SNP) | VAF 20/125 reads (16%) | SIFT tolerated (0.73); PolyPhen possibly damaging (0.499); catalogued as COSV60193500; called by muse, mutect2, varscan2
- TTI1 | c.615G>T p.L205F | Missense Mutation (SNP) | VAF 18/202 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); catalogued as COSV65060722, COSV65061287; called by muse, mutect2
- TTLL9 | c.134G>A p.R45Q | Missense Mutation (SNP) | VAF 16/183 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs371118511, COSV100207126; called by muse, mutect2
- UBXN1 | c.409C>T p.R137W | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV53656345; called by muse, mutect2, varscan2
- UNC5C | c.1651A>G p.S551G | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.045); catalogued as COSV71658408; called by muse, mutect2, varscan2
- VGLL3 | c.478G>T p.A160S | Missense Mutation (SNP) | VAF 38/305 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV67352518; called by muse, mutect2, varscan2
- VPS41 | c.1867T>A p.Y623N | Missense Mutation (SNP) | VAF 36/466 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); catalogued as COSV59646270, COSV59653342; called by muse, mutect2
- XCR1 | c.665G>A p.R222H | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs757552327, COSV100499258, COSV58568820; called by muse, mutect2, varscan2
- ZNF711 | c.1961T>C p.F654S | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.609); catalogued as COSV52151849; called by muse, mutect2, varscan2
- FLG | c.8843_8846del p.R2948Nfs*118 | Frame Shift Del (DEL) | VAF 20/145 reads (14%) | called by mutect2, varscan2
- MAP6 | c.906-1_908dup p.N303Kfs*3 | Frame Shift Ins (INS) | VAF 9/48 reads (19%) | called by mutect2, pindel, varscan2
- PBX2 | c.502del p.I168Sfs*24 | Frame Shift Del (DEL) | VAF 36/198 reads (18%) | called by mutect2, pindel, varscan2
- PPP2R5A | c.785_786del p.L262Sfs*7 | Frame Shift Del (DEL) | VAF 13/118 reads (11%) | called by mutect2, pindel, varscan2
- PRAMEF14 | c.43C>A p.Q15K | Missense Mutation (SNP) | VAF 51/417 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- SMC4 | c.3004G>C p.E1002Q | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.029); called by muse, mutect2
- SUPT20HL2 | c.117dup p.L40Tfs*3 | Frame Shift Ins (INS) | VAF 37/113 reads (33%) | called by mutect2, varscan2
- TOP3B | c.717del p.Y240Tfs*23 | Frame Shift Del (DEL) | VAF 34/177 reads (19%) | called by mutect2, pindel, varscan2
- AGAP1 | c.1842G>A p.S614= (on ENST00000304032 / NM_001037131.3; = p.S561= on NM_014914.5) | Silent (SNP) | VAF 8/160 reads (5%) | catalogued as COSV58318595; called by muse, mutect2
- BIN1 | c.33G>C p.A11= | Silent (SNP) | VAF 11/53 reads (21%) | catalogued as COSV52116270; called by muse, mutect2, varscan2
- CCT6B | c.171C>T p.T57= | Silent (SNP) | VAF 18/121 reads (15%) | catalogued as rs1292389601, COSV58488031; called by muse, mutect2, varscan2
- CLUAP1 | c.1137C>T p.D379= | Silent (SNP) | VAF 26/108 reads (24%) | catalogued as rs377189683, COSV57087883; called by muse, mutect2, varscan2
- CSPG4 | c.1749G>A p.P583= | Silent (SNP) | VAF 20/64 reads (31%) | catalogued as rs777208654, COSV57891445; called by muse, mutect2, varscan2
- ERC1 | c.3162C>T p.D1054= (on ENST00000360905 / NM_178040.4; = p.D1026= on NM_178039.4) | Silent (SNP) | VAF 34/187 reads (18%) | catalogued as rs944958447, COSV61692063; called by muse, mutect2, varscan2
- GLT1D1 | c.804A>G p.V268= (on ENST00000442111 / NM_001366889.1; = p.V188= on NM_144669.3) | Silent (SNP) | VAF 9/102 reads (9%) | catalogued as COSV55879006; called by muse, mutect2, varscan2
- HKDC1 | c.801C>T p.D267= | Silent (SNP) | VAF 42/190 reads (22%) | catalogued as rs766398895, COSV63575722; called by muse, mutect2, varscan2
- HOXB5 | c.393C>T p.T131= | Silent (SNP) | VAF 20/101 reads (20%) | catalogued as COSV53312200; called by muse, mutect2, varscan2
- HTR2C | c.225C>A p.I75= | Silent (SNP) | VAF 33/142 reads (23%) | catalogued as COSV52202886; called by muse, mutect2, varscan2
- KCNA5 | c.483C>T p.N161= | Silent (SNP) | VAF 16/146 reads (11%) | catalogued as COSV52904209; called by muse, mutect2, varscan2
- KIT | c.1860C>T p.V620= | Silent (SNP) | VAF 15/74 reads (20%) | catalogued as rs200814065; ClinVar: likely benign; called by muse, mutect2, varscan2
- LPA | c.2727T>C p.T909= | Silent (SNP) | VAF 39/283 reads (14%) | catalogued as COSV60297902; called by muse, mutect2, varscan2
- MARS2 | c.99C>T p.S33= | Silent (SNP) | VAF 8/126 reads (6%) | catalogued as COSV56570795; called by muse, mutect2
- MTX3 | c.249A>G p.E83= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as COSV72512187; called by muse, mutect2, varscan2
- MUC5B | c.15138C>T p.N5046= | Silent (SNP) | VAF 19/51 reads (37%) | catalogued as rs754101374, COSV71590379; called by muse, mutect2, varscan2
- NCKAP5 | c.3504G>A p.G1168= | Silent (SNP) | VAF 38/107 reads (36%) | catalogued as COSV58430097; called by muse, mutect2, varscan2
- NCKAP5 | c.1083C>T p.L361= | Silent (SNP) | VAF 12/47 reads (26%) | catalogued as COSV58430110; called by muse, mutect2, varscan2
- NEB | c.18207C>T p.I6069= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as COSV50829657; called by muse, mutect2
- PCDH19 | c.663C>T p.T221= | Silent (SNP) | VAF 49/166 reads (30%) | catalogued as COSV55258376; called by muse, mutect2, varscan2
- PLCB1 | c.1299G>A p.G433= | Silent (SNP) | VAF 7/126 reads (6%) | catalogued as COSV62040605; called by muse, mutect2
- PLXNA2 | c.5463C>G p.L1821= | Silent (SNP) | VAF 31/250 reads (12%) | catalogued as COSV65438153; called by muse, mutect2, varscan2
- SLC26A7 | c.1182C>A p.I394= | Silent (SNP) | VAF 33/382 reads (9%) | catalogued as COSV52587235; called by muse, mutect2
- SLC39A5 | c.1218C>T p.F406= | Silent (SNP) | VAF 86/635 reads (14%) | catalogued as COSV57190799; called by muse, mutect2, varscan2
- SNTG1 | c.1224T>C p.H408= | Silent (SNP) | VAF 45/237 reads (19%) | catalogued as COSV52428203; called by muse, mutect2, varscan2
- SPAST | c.1383A>G p.L461= | Silent (SNP) | VAF 25/79 reads (32%) | catalogued as COSV59513009; called by muse, mutect2, varscan2
- SYNE1 | c.13227C>T p.D4409= (on ENST00000367255 / NM_182961.4; = p.D4338= on NM_033071.3) | Silent (SNP) | VAF 16/74 reads (22%) | catalogued as COSV54920414; called by muse, mutect2, varscan2
- TAF1C | c.42C>T p.T14= | Silent (SNP) | VAF 34/72 reads (47%) | catalogued as rs141321804; called by muse, mutect2
- TENM3 | c.7785C>T p.D2595= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as COSV69300258; called by muse, mutect2, varscan2
- TMEM71 | c.246C>T p.C82= | Silent (SNP) | VAF 38/384 reads (10%) | catalogued as rs183699304, COSV63456526; called by muse, mutect2
- TTN | c.13581C>T p.S4527= (on ENST00000591111; = p.S3600= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 47/132 reads (36%) | catalogued as rs977012928, COSV59912778; ClinVar: likely benign; called by muse, mutect2, varscan2
- UTP25 | c.1542T>A p.S514= | Silent (SNP) | VAF 20/88 reads (23%) | catalogued as COSV71965750; called by muse, mutect2, varscan2
- ZNF521 | c.858C>T p.C286= | Silent (SNP) | VAF 17/121 reads (14%) | catalogued as COSV64123161; called by muse, mutect2, varscan2
- ZNF786 | c.906C>A p.G302= | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as COSV100302798; called by mutect2, varscan2
- ZNF324B | c.-33C>T | 5'UTR (SNP) | VAF 19/60 reads (32%) | catalogued as rs754111073, COSV100351587; called by muse, mutect2, varscan2
